TCGA case TCGA-D1-A163 — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: Mayo Clinic. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a438dce7-6592-4ea6-a401-57f5a8fe8ba6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Alive.

Diagnoses (2)
1. Endometrioid adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 50.9 years (18,604 days); Year of diagnosis: 2008; Method of diagnosis: Dilation and Curettage Procedure; FIGO stage: Stage IIIC; FIGO staging edition year: 1995; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 991 days (2.7 years).
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 38.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 2; Lymph nodes tested: 53.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 12.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 74 days; Days to treatment end: 106 days; Treatment dose: 4,500 cGy; Course number: 1; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, Implants; Treatment intent type: Adjuvant; Days to treatment start: 110 days; Days to treatment end: 110 days; Treatment dose: 500 cGy; Course number: 2; Number of fractions: 1; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Days to treatment start: 249 days; Days to treatment end: 281 days; Treatment dose: 4,500 cGy; Course number: 1; Number of fractions: 25; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Days to treatment start: 327 days; Days to treatment end: 327 days; Treatment dose: 1,000 cGy; Course number: 2; Number of fractions: 1; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 343 days; Days to treatment end: 498 days (1.4 years); Number of cycles: 6; Treatment dose: 2,490 mg; Prescribed dose: 175; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 351 days; Days to treatment end: 498 days (1.4 years); Number of cycles: 6; Treatment dose: 5,360 mg; Prescribed dose: 6; Prescribed dose units: AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
2. Metastasis of diagnosis 1 (Endometrioid adenocarcinoma, NOS), site: Intra-abdominal lymph nodes. Age at diagnosis: 51.5 years (18,827 days); Days to diagnosis: 223 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Residual disease: R0.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 223 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to progression: 223 days.
- Days to follow up: 938 days (2.6 years); Disease response: Tumor Free.
- Days to follow up: 991 days (2.7 years); Disease response: Tumor Free.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal replacement therapy status: No; Menopause status: Perimenopausal; Number of pregnancies: 1; Pregnancy outcome: Full Term Birth, NOS.
- Timepoint category: Initial Diagnosis; Weight: 109 kg; Height: 169 cm; BMI: 38.2.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D1-A163-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 170 mg.
  Slide TCGA-D1-A163-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 60; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-D1-A163-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D1-A163-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Peri (6-12 months since last menstrual period); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Surgical approach at diagnosis: open.
- Follow-up form: History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; History tamoxifen use: Never Used; Hypertension diagnosis: No; Diabetes diagnosis indicator: No; Pregnancies full term count: 1; History colorectal cancer: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event site other: Paraaortic retroperitoneal lymphnode; New tumor event type: Metastatic; New tumor event surgery: Yes; New tumor event procedure: Surgical Resection; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Drug treatment 1: Regimen number: 1; Therapy regimen: Recurrence.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: Taxol; Therapy regimen: Recurrence.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 991 days; disease-specific survival: no event (censored), 991 days; disease-free interval: event (new tumor event after initially disease-free), 223 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 223 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D1-A163-01A-11D-A12G-01): tumor purity 0.8, ploidy 2, whole-genome doublings 0.
